Somatic mutation profile of tumor specimen HTMCP-03-06-02081-01A (aliquot HTMCP-03-06-02081-01A-01D-4427) from CGCI case HTMCP-03-06-02081, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7cafa9d-1ec3-41e0-867b-e68d9fd90526.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02081-10A (Blood Derived Normal), aliquot HTMCP-03-06-02081-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0560422f-c4ea-4a0b-a2a9-51786287cd4a

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent.
By variant classification: Silent 8, Missense Mutation 8, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HECW1 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 11/136 reads (8%) | catalogued as COSV67841189; called by muse, mutect2
- INPP4B | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568595082, COSV53715220; called by muse, mutect2, varscan2
- LRCH2 | c.1962C>T p.N654= | Splice Region (SNP) | VAF 43/269 reads (16%) | catalogued as rs782377324, COSV57762435; called by muse, mutect2, varscan2
- MYOCD | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767925734, COSV58498174, COSV58501218; called by muse, mutect2, varscan2
- OSBPL1A | c.2711G>A p.R904H (on ENST00000319481 / NM_080597.4; = p.R391H on NM_018030.4) | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs916672263; called by muse, mutect2, varscan2
- PLD3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757965784, COSV100735106; called by mutect2, varscan2
- ZNF521 | c.1488C>G p.I496M | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV64123337, COSV64131393; called by muse, varscan2
- ZSCAN5A | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs1200016620, COSV54224212; called by muse, mutect2, varscan2
- FAS | c.38del p.T13Sfs*15 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- GPS1 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- PRCC | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TTLL6 | c.2623G>A p.E875K (on ENST00000393382 / NM_001130918.3; = p.E568K on NM_173623.3) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FNBP1 | c.381C>T p.I127= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs775840138; called by mutect2, varscan2
- MAP7D2 | c.924G>A p.T308= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs992419109, COSV65528182; called by muse, mutect2, varscan2
- PDE4DIP | c.1327C>T p.L443= | Silent (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- PDS5A | c.2059C>T p.L687= | Silent (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- PDZD2 | c.4506G>A p.S1502= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs763224127; called by mutect2, varscan2
- ZBTB32 | c.1293C>G p.S431= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99386202; called by mutect2, varscan2
- ZNF521 | c.2283C>T p.F761= | Silent (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- ZNF521 | c.1617C>T p.L539= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV64131389; called by muse, varscan2
